Surgical pathology report (de-identified scan), TCGA case TCGA-4A-A93W, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mary Bird Perkins Cancer Center - Our Lady of the Lake, specimen TCGA-4A-A93W-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]	Accession: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] Sex: F	Date Collected: [REDACTED]
MRN: [REDACTED]	Date Received: [REDACTED]
Requested by: [REDACTED]	Date Reported: [REDACTED]
Account: [REDACTED]	
Patient: [REDACTED]	

Clinical Data: Right renal mass

FINAL PATHOLOGIC DIAGNOSIS

- Right kidney (14 grams), partial nephrectomy: Papillary renal cell carcinoma.
- Right kidney (deep margin): Papillary renal cell carcinoma; new margin free of tumor.

SYNOPTIC REPORT

Tumor site:	Right kidney
Histologic type:	Papillary renal cell carcinoma
- Sarcomatoid features:	Not identified
Histologic (Fuhrman) grade:	G2
Tumor size:	3.6 cm
Tumor focality:	Unifocal
Extent of tumor:	Tumor is limited to kidney
Parenchymal margin:	Negative for malignancy (1.0 cm from tumor)
Angiolymphatic invasion:	Not identified
Surgical Pathology Staging:	pT1a NX

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NOS
064.9
JW 3/26/14

Pathologist, Electronic Signature

SPECIMEN(S) SUBMITTED: GROSS DESCRIPTION

- Right renal mass:** In formalin labeled "right renal mass" is a 14 gram, 4 x 3.3 x 3.3 cm partial nephrectomy specimen. There is a 3.6 cm lobulated pale tan-red mass present. The mass abuts and elevates the renal capsule; however, no invasion into or through the capsule is noted. The mass is grossly present, however, at the deep parenchymal resection margin. The perinephric fat is inked black, with the parenchymal margin inked blue. Representative sections submitted in four cassettes, A through D.
- Deep margin:** In formalin labeled "deep margin" is a 3.3 x 1.3 x 1.2 cm portion of renal parenchyma, with an attached portion of lobulated pale tan-red tumor and an additional 2.5 x 2.5 x 1.3 cm aggregate of loose tumor fragments. The tumor is grossly 1 cm from what appears to be the true deep margin, which is inked blue. Representative sections submitted in two cassettes, A and B.

CPT CODE(S):

ICD-9 CODE(S):

FACILITY:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT - CONTINUED

Patient: [REDACTED]

Result ID: [REDACTED]

Accession: [REDACTED]

88307, 88305

END OF REPORT

Source: NCI Genomic Data Commons file 7ee78fa0-acf8-4c14-9767-33d1593c2500 (TCGA-4A-A93W.709348FB-E674-4720-B651-901E74E65449.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).